Somatic mutation profile of tumor specimen TCGA-HD-8634-01A (aliquot TCGA-HD-8634-01A-11D-2394-08) from TCGA case TCGA-HD-8634, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 51.2 years (18,718 days).
Specimen TCGA-HD-8634-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 388fbec8-2c43-4f8d-9298-fed35997aebe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HD-8634-10A (Blood Derived Normal), aliquot TCGA-HD-8634-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02fa31a7-3b4f-4e7c-a0a8-cb30f34f3e3d

The open-access MAF lists 64 somatic variants for this specimen: 46 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 16, Frame Shift Ins 3, Intron 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMELX | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV100499157; called by muse, mutect2, varscan2
- ANKRD42 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99474188; called by muse, mutect2
- ATP7A | c.3235A>G p.T1079A | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100431729; called by muse, mutect2, varscan2
- AXIN1 | c.2577G>C p.E859D | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99250330; called by muse, mutect2
- BRWD1 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV100314182; called by muse, mutect2
- CACNA1C | c.4951C>A p.L1651M | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV100222338, COSV59756728; called by muse, mutect2
- CAPN6 | c.1555C>G p.Q519E | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.908); catalogued as rs369793546, COSV100137102; called by muse, mutect2, varscan2
- CFH | c.2962G>T p.D988Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV100810218; called by muse, mutect2, varscan2
- COL17A1 | c.1685A>G p.N562S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV100793375; called by muse, mutect2
- COL4A1 | c.2490C>G p.F830L | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.961); catalogued as COSV101011611, COSV65433513; called by muse, mutect2, varscan2
- COL6A6 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371005676; called by mutect2, varscan2
- DDB2 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751910498, COSV99921911; called by muse, mutect2, varscan2
- ENAM | c.3037G>A p.D1013N | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.347); catalogued as COSV101253344; called by muse, mutect2, varscan2
- EVPL | c.4143C>G p.D1381E | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV101440975; called by muse, mutect2, varscan2
- EXPH5 | c.5000A>T p.K1667M | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV99762222; called by muse, mutect2, varscan2
- FBXO9 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs1310462278, COSV99762664; called by muse, mutect2, varscan2
- FCRL1 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.732); catalogued as rs756516538, COSV100839699, COSV63823726; called by muse, mutect2, varscan2
- GET4 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as rs573133720, COSV56256303; called by muse, mutect2, varscan2
- GMDS | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs1223395243, COSV66417692; called by muse, mutect2, varscan2
- GMIP | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV99179604; called by muse, mutect2, varscan2
- HIP1R | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99459313; called by muse, mutect2, varscan2
- INSM2 | c.1393G>A p.G465S | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1455509602, COSV99356127; called by muse, mutect2, varscan2
- KDM3B | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV100070250; called by muse, mutect2, varscan2
- KMT2B | c.2723A>T p.D908V | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV99720665; called by muse, mutect2
- LINGO2 | c.1562C>A p.S521Y | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100431256; called by muse, mutect2, varscan2
- MAP1A | c.7063G>A p.E2355K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs1348722691, COSV100289253; called by muse, mutect2, varscan2
- NPPB | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV100916117; called by muse, mutect2
- OPHN1 | c.962G>T p.C321F | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100830778; called by muse, mutect2
- OR2G6 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs138211669; called by mutect2, varscan2
- PCDHA9 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as rs1554143411, COSV65325043; called by muse, mutect2, varscan2
- PCDHGB4 | c.622T>C p.Y208H | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99547206; called by muse, mutect2, varscan2
- PKP4 | c.2597C>T p.A866V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.544); catalogued as rs754780372, COSV61578733; called by muse, mutect2, varscan2
- PLEKHH2 | c.3384G>A p.M1128I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV99175108; called by muse, mutect2, varscan2
- SOWAHD | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100673187; called by muse, mutect2
- TANC1 | c.3812-1G>A p.X1271_splice | Splice Site (SNP) | VAF 3/29 reads (10%) | catalogued as COSV99714670, COSV99715243; called by muse, mutect2, varscan2
- TUBGCP4 | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.111); catalogued as COSV99539377, COSV99539453; called by muse, mutect2, varscan2
- VCAN | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV99427372; called by muse, mutect2, varscan2
- YLPM1 | c.2903G>C p.G968A | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.199); catalogued as COSV99461410; called by muse, mutect2
- ZNF33B | c.872C>G p.S291C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.315); catalogued as COSV100847784; called by muse, mutect2, varscan2
- ZNF589 | c.345A>C p.Q115H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.261); catalogued as COSV100685820; called by muse, mutect2, varscan2
- C1QTNF3 | c.303dup p.G102Wfs*40 | Frame Shift Ins (INS) | VAF 6/70 reads (9%) | called by mutect2, pindel
- DOK1 | c.1086dup p.D363* | Frame Shift Ins (INS) | VAF 9/73 reads (12%) | called by mutect2, pindel, varscan2
- RFC1 | c.1255_1257del p.E419del | In Frame Del (DEL) | VAF 20/100 reads (20%) | called by mutect2, pindel, varscan2
- SESN2 | c.350dup p.M118Hfs*25 | Frame Shift Ins (INS) | VAF 16/69 reads (23%) | called by mutect2, pindel, varscan2
- CHST15 | c.1632C>T p.N544= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs1007131404, COSV100655373; called by muse, mutect2, varscan2
- D2HGDH | c.1326C>G p.L442= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV100344956; called by muse, mutect2, varscan2
- FRMPD4 | c.870C>T p.V290= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV101044096; called by muse, mutect2, varscan2
- KIF5B | c.1932G>A p.K644= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV100192394; called by muse, mutect2
- LAMA5 | c.7947G>A p.Q2649= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99442373; called by muse, mutect2, varscan2
- MAGEC1 | c.1662G>A p.Q554= | Silent (SNP) | VAF 76/395 reads (19%) | catalogued as COSV99596558; called by muse, mutect2, varscan2
- MUC5AC | c.645C>T p.N215= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as rs780428239, COSV62254411; called by muse, mutect2
- NEUROD2 | c.574C>T p.L192= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100223214; called by muse, mutect2, varscan2
- OGDHL | c.600C>A p.T200= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV100934535; called by muse, mutect2
- PCDHB8 | c.2109C>T p.L703= | Silent (SNP) | VAF 38/254 reads (15%) | catalogued as COSV50820859; called by muse, mutect2, varscan2
- PHTF1 | c.399C>T p.C133= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV100760197; called by muse, mutect2
- RHBDD2 | c.270C>T p.F90= | Silent (SNP) | VAF 13/169 reads (8%) | catalogued as rs368904185; called by muse, mutect2
- SLCO3A1 | c.282C>T p.L94= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100575918; called by muse, varscan2
- TENM1 | c.2781C>T p.L927= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as rs996400990, COSV64430417; called by muse, mutect2, varscan2
- TRIM54 | c.240G>A p.S80= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs540676343, COSV56081948; called by mutect2, varscan2
- TSHZ1 | c.2241C>T p.S747= (on ENST00000580243 / NM_001308210.2; = p.S702= on NM_005786.6) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs762347831, COSV100433948; called by muse, mutect2, varscan2
- EYA4 | c.1757-64G>C | Intron (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100766372; called by muse, mutect2, varscan2
- NUP214 | c.6075-916G>A | Intron (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
